Somatic mutation profile of tumor specimen TCGA-C5-A7CJ-01A (aliquot TCGA-C5-A7CJ-01A-11D-A32I-09) from TCGA case TCGA-C5-A7CJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 42.9 years (15,652 days).
Specimen TCGA-C5-A7CJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55488e7d-e265-4751-8d4e-304944240547.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7CJ-10A (Blood Derived Normal), aliquot TCGA-C5-A7CJ-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59148168-d683-435f-a53e-f10139127379

The open-access MAF lists 74 somatic variants for this specimen: 48 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 25, Nonsense Mutation 4, Frame Shift Del 1, Intron 1, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 19/117 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGFG2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53545105; called by muse, mutect2, varscan2
- AKAP12 | c.4268C>T p.A1423V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs1269478109, COSV53573329, COSV53576009; called by muse, mutect2, varscan2
- CDH10 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.423); catalogued as rs893259614, COSV52598214; called by muse, mutect2, varscan2
- CLTCL1 | c.2393G>C p.R798T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV54239634; called by muse, mutect2, varscan2
- COL15A1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV66649306; called by muse, mutect2, varscan2
- COL8A1 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292621126, COSV53743121; called by muse, mutect2, varscan2
- CRPPA | c.1156C>T p.Q386* (on ENST00000407010 / NM_001368197.1; = p.Q336* on NM_001101417.4) | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV67907137, COSV67908820; called by muse, mutect2, varscan2
- DIO3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs369038196; called by muse, mutect2, varscan2
- DOP1B | c.4566G>C p.L1522F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs775264949, COSV67696230; called by muse, mutect2, varscan2
- DSCAML1 | c.839-1G>A p.X280_splice (on ENST00000321322; = p.X220_splice on NM_020693.4) | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV58402968; called by muse, mutect2, varscan2
- EP400 | c.5636G>A p.R1879H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.9); catalogued as rs376569991, COSV57786710; called by muse, mutect2, varscan2
- FAM227B | c.156C>G p.C52W | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as COSV54819756; called by muse, mutect2, varscan2
- FAM98A | c.512T>C p.I171T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1049137996, COSV53211944; called by muse, mutect2, varscan2
- FLG | c.6654C>A p.D2218E | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.094); catalogued as COSV64249596; called by muse, mutect2, varscan2
- FOXC1 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV66516709; called by muse, mutect2, varscan2
- GAL3ST3 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV61749726; called by muse, mutect2, varscan2
- INPP5J | c.1627G>A p.V543M (on ENST00000331075 / NM_001284285.2; = p.V175M on NM_001002837.2) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529365616, COSV58511529; called by muse, mutect2, varscan2
- KBTBD4 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV58597937; called by muse, mutect2, varscan2
- KMT2B | c.7177G>A p.E2393K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV55821716; called by muse, mutect2, varscan2
- LIN7A | c.39C>G p.D13E | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV54017558, COSV54028394; called by muse, mutect2, varscan2
- LRRK2 | c.6574G>C p.E2192Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV54171209; called by muse, mutect2, varscan2
- MATR3 | c.1238A>G p.Y413C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.431); catalogued as COSV63080111; called by muse, mutect2, varscan2
- MAZ | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.61); catalogued as COSV99361342; called by muse, varscan2
- MRGPRX1 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as rs1364627192, COSV57106743; called by muse, mutect2, varscan2
- MYPN | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62739561; called by mutect2, varscan2
- NOS3 | c.2590G>A p.D864N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99871946; called by muse, mutect2, varscan2
- OR51F1 | c.330G>T p.M110I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV58580881; called by muse, mutect2, varscan2
- P4HTM | c.1343G>A p.R448H (on ENST00000383729 / NM_177939.3; = p.R509H on NM_177938.2) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV59087132; called by muse, varscan2
- P4HTM | c.1462G>A p.E488K (on ENST00000383729 / NM_177939.3; = p.E549K on NM_177938.2) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.427); catalogued as rs1157964402, COSV59089239; called by muse, varscan2
- PCSK5 | c.4256G>A p.R1419K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70452822; called by muse, mutect2
- PRPSAP1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.233); catalogued as rs375906385; called by muse, mutect2, varscan2
- RBM27 | c.2854C>T p.R952* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV54594783; called by muse, mutect2, varscan2
- RGS3 | c.3554A>G p.Y1185C (on ENST00000350696 / NM_001282923.2; = p.Y904C on NM_130795.4) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59522554; called by muse, mutect2, varscan2
- RLBP1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as COSV51529467; called by muse, mutect2, varscan2
- RNF17 | c.4603C>T p.H1535Y | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1430763186, COSV55051901; called by muse, mutect2, varscan2
- RPAP2 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV72509671; called by muse, mutect2, varscan2
- RXFP1 | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV57056850; called by muse, mutect2, varscan2
- SLC18B1 | c.233G>A p.C78Y | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV51594202, COSV51596415; called by muse, mutect2, varscan2
- TFAP2E | c.957C>A p.F319L | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV64697505; called by muse, mutect2, varscan2
- TOP1MT | c.1218G>A p.T406= | Splice Region (SNP) | VAF 9/98 reads (9%) | catalogued as COSV61317283; called by muse, mutect2
- TUBB | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100013427; called by muse, mutect2
- WDR6 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as rs1292019419, COSV58247529; called by muse, mutect2, varscan2
- WDR6 | c.2812G>A p.D938N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58247542; called by muse, mutect2
- WNK3 | c.4318G>A p.E1440K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV63615979; called by muse, mutect2, varscan2
- ANLN | c.3303del p.K1101Nfs*33 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- ELOA3B | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- SPATA5L1 | c.1647_1651dup p.R551Hfs*43 | Frame Shift Ins (INS) | VAF 18/105 reads (17%) | called by mutect2, pindel, varscan2
- ALDH8A1 | c.690C>T p.T230= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs138741870; called by muse, mutect2, varscan2
- AXIN1 | c.1344G>A p.P448= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1391375571, COSV51993541; called by muse, mutect2, varscan2
- CACNA1S | c.3039C>T p.F1013= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs139235699; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD2 | c.4983C>T p.F1661= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV53964495; called by muse, mutect2, varscan2
- DOP1B | c.4710G>A p.K1570= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV101215666; called by muse, mutect2, varscan2
- FICD | c.234G>A p.P78= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs374636127; called by muse, mutect2, varscan2
- GPR179 | c.6996G>A p.Q2332= (on ENST00000621958; = p.Q2331= on NM_001004334.4) | Silent (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- ID1 | c.372G>T p.P124= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs752043664, COSV65888905; called by muse, mutect2, varscan2
- KLF3 | c.354C>T p.G118= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1208812123, COSV54712689; called by muse, mutect2
- KLK13 | c.399G>T p.P133= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV50067601; called by muse, mutect2, varscan2
- MTHFD2L | c.927C>T p.F309= (on ENST00000395759 / NM_001144978.2; = p.F251= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs751828571, COSV57469381; called by muse, mutect2, varscan2
- NTRK3 | c.1494C>A p.P498= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV58144185; called by muse, mutect2
- PCDH12 | c.2331C>T p.L777= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs558542016, COSV51523957, COSV99191795; called by muse, mutect2, varscan2
- PTGDR | c.708G>A p.P236= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1172867034, COSV60094994; called by muse, mutect2, varscan2
- RNASEL | c.1611C>T p.I537= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- RNF125 | c.687G>A p.S229= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs374540528; called by muse, mutect2, varscan2
- STXBP4 | c.402C>G p.A134= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV54843901; called by muse, mutect2, varscan2
- SUV39H2 | c.261G>A p.P87= (on ENST00000354919 / NM_001193424.2; = p.P27= on NM_024670.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs760782631, COSV57955608; called by muse, mutect2, varscan2
- TIMM44 | c.1125C>T p.V375= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs369918101, COSV54494716; called by mutect2, varscan2
- TRHR | c.733C>T p.L245= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1303198383, COSV61236590; called by muse, mutect2, varscan2
- TTN | c.96387G>A p.L32129= (on ENST00000591111; = p.L24705= on NM_003319.4) | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV100622575; called by muse, mutect2
- TTN | c.42387G>A p.V14129= (on ENST00000591111; = p.V6705= on NM_003319.4) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV59890310, COSV60005949; called by muse, mutect2, varscan2
- UNC13B | c.1161G>A p.L387= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as COSV101037019; called by muse, mutect2
- ZC3H7B | c.18G>A p.R6= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV60964729; called by muse, mutect2, varscan2
- ZFHX4 | c.3234G>A p.R1078= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV50670077; called by muse, mutect2, varscan2
- RIMS2 | c.4064-21224G>T | Intron (SNP) | VAF 22/105 reads (21%) | catalogued as COSV51724762; called by muse, mutect2, varscan2
